Somatic mutation profile of tumor specimen ALCH-AEL8-TTP1-A (aliquot ALCH-AEL8-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AEL8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.2 years (21,990 days).
Specimen ALCH-AEL8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdb2e4b7-714d-4f2a-825f-09c9f7020295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEL8-NB1-A (Blood Derived Normal), aliquot ALCH-AEL8-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b9c3d78-8624-4ce8-b542-8f642c329687

The open-access MAF lists 42 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Intron 5, In Frame Del 3, Nonsense Mutation 2, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 30/146 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AL121899.2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1259803578, COSV67350680; called by muse, varscan2
- APLNR | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57242011; called by muse, mutect2, varscan2
- ARL13A | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs867009010; called by muse, mutect2, varscan2
- DVL3 | c.1861_1884del p.P621_A628del | In Frame Del (DEL) | VAF 28/154 reads (18%) | catalogued as rs1224771850; called by mutect2, pindel
- GPR158 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100893674; called by muse, mutect2, varscan2
- HOXC12 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186089788; called by muse, mutect2, varscan2
- KCNC2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100129849, COSV54365172; called by muse, mutect2, varscan2
- NUMA1 | c.5911C>T p.Q1971* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as rs1213736122, COSV104390239; called by muse, mutect2, varscan2
- RBMS3 | c.1273G>A p.E425K (on ENST00000383767 / NM_001003793.3; = p.E409K on NM_014483.3) | Missense Mutation (SNP) | VAF 87/412 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); catalogued as rs754919318; called by muse, mutect2, varscan2
- RNF150 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV60789165, COSV60795272; called by muse, mutect2, varscan2
- RNF150 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60800253; called by muse, mutect2, varscan2
- TSGA10 | c.840dup p.S281Ifs*2 | Frame Shift Ins (INS) | VAF 58/296 reads (20%) | catalogued as rs781578889; called by mutect2, varscan2
- CMYA5 | c.1196_1201del p.E399_L400del | In Frame Del (DEL) | VAF 58/210 reads (28%) | called by mutect2, pindel, varscan2
- E2F7 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 98/571 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM186A | c.6004A>T p.I2002L | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FREM1 | c.2983T>C p.Y995H | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- GNPTG | c.469T>C p.C157R | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM1 | c.2531G>A p.R844K | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HYAL1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ICE1 | c.5392_5400del p.T1798_T1800del | In Frame Del (DEL) | VAF 51/246 reads (21%) | called by mutect2, pindel, varscan2
- IFI35 | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- PRG4 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 24/663 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PROS1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RNF213 | c.14819A>G p.Q4940R | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SETBP1 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SIRT3 | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM260 | c.935C>G p.A312G | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CACNA1I | c.165G>A p.A55= | Silent (SNP) | VAF 40/238 reads (17%) | catalogued as rs1172467757, COSV60808105; called by muse, mutect2, varscan2
- MEA1 | c.93C>T p.P31= | Silent (SNP) | VAF 46/192 reads (24%) | catalogued as COSV55146507; called by muse, mutect2, varscan2
- MKRN1 | c.273G>A p.K91= | Silent (SNP) | VAF 103/374 reads (28%) | called by muse, mutect2, varscan2
- OR13D1 | c.507C>T p.N169= | Silent (SNP) | VAF 69/288 reads (24%) | catalogued as rs1426580514, COSV59513749, COSV59514543; called by muse, mutect2, varscan2
- SEPTIN12 | c.174C>T p.S58= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs763596107, COSV99190520; called by muse, mutect2, varscan2
- STXBP3 | c.243C>A p.I81= | Silent (SNP) | VAF 78/359 reads (22%) | called by muse, mutect2, varscan2
- ZNF91 | c.3267A>G p.Q1089= | Silent (SNP) | VAF 64/246 reads (26%) | catalogued as rs375072097; called by muse, mutect2, varscan2
- ABHD16A | c.132+445T>C | Intron (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/34 reads (18%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- AKR1C2 | c.369+124C>G | Intron (SNP) | VAF 42/259 reads (16%) | catalogued as COSV101060378; called by muse, mutect2, varscan2
- C12orf57 | c.*51C>G | 3'UTR (SNP) | VAF 26/132 reads (20%) | called by muse, varscan2
- C2CD6 | c.1581+1371A>C | Intron (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- CT55 | c.-1G>T | 5'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- TNPO2 | c.-13-358C>T | Intron (SNP) | VAF 9/46 reads (20%) | catalogued as COSV63509647; called by muse, mutect2, varscan2
